Somatic mutation profile of tumor specimen BA2540D (aliquot aq-BA2540D) from BEATAML1.0 case 2176, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with t(9;11)(p22;q23), MLLT3-MLL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.7 years (25,444 days).
Specimen BA2540D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a742b251-a607-4bea-9f5c-5a84dd437ad5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2818D (Solid Tissue Normal), aliquot aq-BA2818D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d82e2cde-c863-4428-8266-50254acc18a8

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs949596399; called by muse, mutect2
- STAB2 | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs140108777, COSV101186275; called by mutect2, varscan2
- ARMC6 | c.793C>A p.H265N (on ENST00000392336; = p.H240N on NM_033415.4) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CACNA2D3 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH20 | c.951T>C p.D317= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as rs1170742157; called by muse, mutect2, varscan2
- KSR2 | c.1740G>A p.P580= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as rs768440495, COSV56673146; called by muse, mutect2, varscan2
- ZFP2 | c.1383G>A p.T461= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs912162546, COSV63726973; called by muse, mutect2, varscan2
- GGCX | c.374-11A>G | Intron (SNP) | VAF 82/158 reads (52%) | catalogued as rs772475416; called by mutect2, varscan2
